CPTAC case C3L-08144 — Stomach — Adenomas and Adenocarcinomas (CPTAC-3)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of the Clinical Proteomic Tumor Analysis Consortium (CPTAC). Disease type: Adenomas and Adenocarcinomas; Primary site: Stomach. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/daada11b-057d-4a12-9a79-52fa101b7dcb

Demographics
Sex at birth: male; Race: white; Year of birth: 1949; Vital status: Alive; Country of birth: Ukraine.

Diagnoses (1)
1. Adenocarcinoma, NOS: ICD-O-3 morphology code: 8140/3; Tissue or organ of origin: Stomach, NOS; Site of resection or biopsy: Body of stomach; Age at diagnosis: 72.0 years (26,311 days); Year of diagnosis: 2021; AJCC staging edition: 8th; AJCC pathologic T: T4b; AJCC pathologic N: N3a; AJCC pathologic stage: Stage IIIC; Tumor grade: G1; Residual disease: R0; Days to last known disease status: 747 days (2.0 years); Progression or recurrence: no; Days to last follow up: 747 days (2.0 years); Tumor focality: Unifocal.
   Pathology details: Greatest tumor dimension: 10 cm; Lymph node involvement: Positive; Lymph nodes positive: 8; Lymph nodes tested: 12.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Docetaxel; Days to treatment start: 96 days; Days to treatment end: 102 days; Treatment outcome: Stable Disease.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Docetaxel; Days to treatment start: 96 days; Days to treatment end: 102 days; Treatment outcome: Complete Response.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Fluorouracil; Days to treatment start: 132 days; Days to treatment end: 139 days; Treatment outcome: Complete Response.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Fluorouracil; Days to treatment start: 132 days; Days to treatment end: 139 days; Treatment outcome: Stable Disease.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Oxaliplatin; Days to treatment start: 195 days; Days to treatment end: 202 days; Treatment outcome: Stable Disease.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Oxaliplatin; Days to treatment start: 195 days; Days to treatment end: 202 days; Treatment outcome: Complete Response.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Cisplatin; Days to treatment start: 255 days; Days to treatment end: 262 days; Treatment outcome: Stable Disease.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Cisplatin; Days to treatment start: 255 days; Days to treatment end: 262 days; Treatment outcome: Complete Response.

Follow-up (2 entries)
- Days to follow up: 495 days (1.4 years); Disease response: Complete Response; Karnofsky performance status: 90; ECOG performance status: 0.
- Days to follow up: 747 days (2.0 years); Disease response: Complete Response; Karnofsky performance status: 90; ECOG performance status: 0.

Exposures
- Tobacco smoking status: Current Reformed Smoker, Duration Not Specified; Cigarettes per day: 15; Alcohol history: Yes; Alcohol intensity: Non-Drinker; Secondhand smoke as child: Yes; Type of smoke exposure: Smoke exposure, NOS.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample C3L-08144-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Stomach; Preservation method: Snap Frozen; Freezing method: LN2; Days to sample procurement: 17 days; Initial weight: 590 mg; Method of sample procurement: Tumor Resection; Diagnosis pathologically confirmed: Yes.
  Slide C3L-08144-21: Section location: Body; Percent tumor nuclei: 60; Percent necrosis: 5.
- Sample C3L-08144-04: Sample type: Solid Tissue Normal; Tissue type: Normal; Specimen type: Solid Tissue; Biospecimen anatomic site: Stomach; Preservation method: Snap Frozen; Freezing method: LN2; Days to sample procurement: 17 days; Initial weight: 700 mg; Method of sample procurement: Surgical Resection; Diagnosis pathologically confirmed: Yes.
- Sample C3L-08144-31: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood Components NOS; Biospecimen anatomic site: Blood; Preservation method: Frozen; Freezing method: -20 (unit not recorded by GDC); Days to sample procurement: 17 days; Method of sample procurement: Blood Draw.
